Somatic mutation profile of tumor specimen TCGA-D1-A16Q-01A (aliquot TCGA-D1-A16Q-01A-12D-A12J-09) from TCGA case TCGA-D1-A16Q, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 54.4 years (19,873 days).
Specimen TCGA-D1-A16Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17df4455-cde1-4e46-99a6-aababd78ec21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16Q-10A (Blood Derived Normal), aliquot TCGA-D1-A16Q-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dfb3a25-4714-4158-8b91-a2704935cb18

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 4, Splice Site 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 84/218 reads (39%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 69/156 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1336_1353del p.G446_E451del (on ENST00000521381 / NM_181523.3; = p.G176_E181del on NM_181504.4) | In Frame Del (DEL) | VAF 75/223 reads (34%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 167/433 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 87/211 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060500126, CM032998, COSV64291751, COSV64292375; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 48/101 reads (48%) | catalogued as COSV61379484; called by muse, mutect2, varscan2
- BEGAIN | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs746464797, COSV62068826; called by muse, mutect2, varscan2
- CD4 | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV50596361; called by muse, mutect2, varscan2
- DCHS1 | c.8672G>A p.R2891Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs60443131; called by muse, mutect2, varscan2
- FARSA | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750867053, COSV58906061; called by muse, mutect2, varscan2
- FLVCR2 | c.881A>G p.D294G | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs201655143, COSV53164539; called by muse, mutect2, varscan2
- FOXA2 | c.488C>T p.S163L (on ENST00000377115 / NM_153675.3; = p.S169L on NM_021784.5) | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65797106; called by muse, mutect2, varscan2
- FTSJ3 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 25/494 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs771302233, COSV63791434; called by muse, mutect2
- IGSF10 | c.1777C>G p.L593V | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV56791834; called by muse, mutect2, varscan2
- MORC4 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 141/373 reads (38%) | catalogued as COSV55246592; called by muse, mutect2, varscan2
- MYOF | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63710782; called by muse, mutect2, varscan2
- NFIX | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV62181142; called by muse, mutect2, varscan2
- OR10P1 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.564); catalogued as COSV59006931, COSV59008477; called by muse, mutect2, varscan2
- OR5AS1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 125/322 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs775842242, COSV57981863, COSV57983631; called by muse, mutect2, varscan2
- PARD3 | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 123/312 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60762313; called by muse, mutect2, varscan2
- QSOX1 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV62581636; called by muse, mutect2, varscan2
- SLC9C2 | c.228+2T>C p.X76_splice | Splice Site (SNP) | VAF 75/197 reads (38%) | catalogued as COSV62949564; called by muse, mutect2, varscan2
- SOGA1 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.724); catalogued as rs1396229230, COSV52931275; called by muse, mutect2, varscan2
- TMEM131 | c.1187C>G p.S396W | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV51786434; called by muse, mutect2, varscan2
- AKAP4 | c.277-3dup | Splice Region (INS) | VAF 19/57 reads (33%) | called by mutect2, varscan2
- PPP4R1 | c.2539_2540dup p.C848Sfs*25 (on ENST00000400556 / NM_001042388.3; = p.C831Sfs*25 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 50/152 reads (33%) | called by mutect2, pindel, varscan2
- UBE2NL | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- DDIT4L | c.48A>T p.S16= | Silent (SNP) | VAF 56/109 reads (51%) | catalogued as COSV56768073; called by muse, mutect2, varscan2
- FAT4 | c.2415C>T p.N805= | Silent (SNP) | VAF 115/282 reads (41%) | catalogued as rs747689582, COSV67900496; called by muse, mutect2, varscan2
- GAL3ST1 | c.765C>T p.F255= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs777987176, COSV58892247; called by muse, mutect2, varscan2
- KIAA1755 | c.573C>T p.P191= | Silent (SNP) | VAF 10/310 reads (3%) | catalogued as COSV54080824; called by muse, mutect2
- LRRFIP2 | c.1521C>T p.L507= | Silent (SNP) | VAF 193/492 reads (39%) | catalogued as COSV60870586; called by muse, mutect2, varscan2
- MYO15A | c.4215C>T p.N1405= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1163933682, COSV52766393; called by muse, mutect2, varscan2
- H4C5 | c.-1C>T | 5'UTR (SNP) | VAF 58/155 reads (37%) | catalogued as rs144621549, COSV100747949; called by muse, mutect2, varscan2
